Gene-level copy-number profile of tumor specimen MP2PRT-PASNHU-TMP1-A from MP2PRT case MP2PRT-PASNHU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,400 days).
Specimen MP2PRT-PASNHU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2968885-6084-4ea0-9dfb-18e6d5a43b6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASNHU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/44fdeff0-1bd5-4dca-ad12-e420560cce49

Most common (modal) total copy number across autosomal genes: 0 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 31,478; copy number 1: 2,717; copy number 2: 143; copy number 3: 18,477; copy number 4: 2,018; copy number 5: 329; copy number 6: 2,967; copy number 7: 264; copy number 8: 9.

Caution: the most common total copy number in this file is 0 (31,478 autosomal genes at 0 copies), which is not a plausible tumor genome; the fit is treated as unreliable and no deletion or amplification regions are listed.

Homozygous deletions (total copy number 0; autosomes only): 31,478 genes in 15 contiguous regions (regions not listed; see the caution above).

Amplified relative to the modal value (total copy number ≥ 1, i.e. more than twice the modal value of 0; autosomes only): 24,580 genes in 20 contiguous regions (regions not listed; see the caution above).

Autosomal genes at a single copy (total copy number 1): 2,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
